CCDI case PBCTUC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/376194fe-62bf-4b81-84a1-9dbd2a1e8453

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,366 days).

Biospecimens (3 samples)
- Sample 0DZ4M4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZ4MF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZ4O0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
